Somatic mutation profile of tumor specimen ALCH-AE0J-TTP1-A (aliquot ALCH-AE0J-TTP1-A-1-0-D-A604-36) from ALCHEMIST case ALCH-AE0J, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 73.4 years (26,817 days).
Specimen ALCH-AE0J-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e34fe2ba-eb9d-4346-a14a-25619ae841d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE0J-NB1-A (Blood Derived Normal), aliquot ALCH-AE0J-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3ac6a4f-d02b-420e-b2ae-9304b9b53dec

The open-access MAF lists 117 somatic variants for this specimen: 85 protein-altering or splice-affecting, 23 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 23, Intron 6, Nonsense Mutation 5, 5'Flank 2, RNA 1, Frame Shift Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.565C>G p.R189G | Missense Mutation (SNP) | VAF 26/449 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60912531; called by muse, mutect2
- ACTB | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV59318368; called by muse, mutect2
- CASZ1 | c.3425C>T p.S1142L | Missense Mutation (SNP) | VAF 23/314 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs749636741; called by muse, mutect2
- CDH18 | c.2080G>T p.E694* | Nonsense Mutation (SNP) | VAF 34/280 reads (12%) | catalogued as COSV56947941; called by muse, mutect2, varscan2
- CPN2 | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 27/406 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.326); catalogued as rs1438277511, COSV60470800; called by muse, mutect2
- CST9L | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 22/364 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV65408090; called by muse, mutect2
- CXCL3 | c.297G>T p.K99N | Missense Mutation (SNP) | VAF 34/538 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs748177839; called by muse, mutect2
- FGF14 | c.618C>G p.Y206* | Nonsense Mutation (SNP) | VAF 76/636 reads (12%) | catalogued as COSV65934689; called by muse, mutect2, varscan2
- GK3P | c.20C>A p.A7E | Missense Mutation (SNP) | VAF 38/828 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.075); catalogued as COSV56978408; called by muse, mutect2
- HIF1A | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs559928080; called by muse, mutect2
- HSD17B14 | c.548C>A p.S183Y | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV54413384; called by muse, mutect2
- IL10 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100894757; called by muse, mutect2
- IL10 | c.124C>G p.R42G | Missense Mutation (SNP) | VAF 28/678 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs1274280163, COSV65594970; called by muse, mutect2
- IQCB1 | c.346C>G p.L116V | Missense Mutation (SNP) | VAF 25/641 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV60435145; called by muse, mutect2
- OR10Z1 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 30/454 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV100778936, COSV63524662; called by muse, mutect2
- OR2T4 | c.415C>A p.L139I | Missense Mutation (SNP) | VAF 64/442 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV63543772; called by muse, mutect2, varscan2
- OR5L1 | c.117G>T p.L39F | Missense Mutation (SNP) | VAF 30/471 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1302393183, COSV100450187, COSV61734611; called by muse, mutect2
- PYGL | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 36/662 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs758005615, COSV53587096, COSV99368746; called by muse, mutect2
- RYR1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 32/383 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.274); catalogued as rs1207497085; called by muse, mutect2
- SHISA9 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1226938626, COSV69631698; called by muse, mutect2
- TPO | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 16/496 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.581); catalogued as rs1021279074; called by muse, mutect2
- UGT2B7 | c.1096C>G p.P366A | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.751); catalogued as rs1004652217, COSV59441838, COSV59445585; called by muse, mutect2
- AHNAK2 | c.7562C>T p.S2521F | Missense Mutation (SNP) | VAF 28/525 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2
- ALDH1A2 | c.288G>C p.R96S | Missense Mutation (SNP) | VAF 47/667 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.021); called by muse, mutect2
- ART4 | c.616C>A p.Q206K | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.944); called by muse, mutect2
- ATP6V0A4 | c.2142C>G p.F714L | Missense Mutation (SNP) | VAF 29/494 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.914); called by muse, mutect2
- BEND4 | c.1489G>T p.G497W | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRAF | c.673G>T p.E225* | Nonsense Mutation (SNP) | VAF 39/714 reads (5%) | called by muse, mutect2
- C1QTNF6 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- C20orf96 | c.400C>G p.Q134E (on ENST00000360321 / NM_153269.3; = p.Q133E on NM_080571.1) | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.647); called by muse, mutect2
- C5orf52 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.14); called by muse, mutect2
- CBARP | c.115T>G p.Y39D (on ENST00000382477; = p.Y45D on NM_152769.3) | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); called by muse, mutect2
- CD248 | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.275); called by muse, mutect2
- CDC7 | c.1207A>G p.I403V | Missense Mutation (SNP) | VAF 19/186 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.3); called by muse, mutect2
- CEP162 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 20/514 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.443); called by muse, mutect2
- COL22A1 | c.2746G>T p.G916* | Nonsense Mutation (SNP) | VAF 42/257 reads (16%) | called by muse, mutect2, varscan2
- COL7A1 | c.4309C>G p.P1437A | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2
- COL9A1 | c.13T>C p.W5R | Missense Mutation (SNP) | VAF 17/546 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- FAT3 | c.5635A>T p.N1879Y | Missense Mutation (SNP) | VAF 19/334 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- FIGNL1 | c.1774G>C p.E592Q | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.033); called by muse, mutect2
- FIP1L1 | c.343A>G p.T115A | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2
- GABARAPL2 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 24/300 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.172); called by muse, mutect2
- GLYR1 | c.1662A>T p.*554Yext*14 | Nonstop Mutation (SNP) | VAF 25/248 reads (10%) | called by muse, mutect2, varscan2
- GRIN2A | c.1178A>G p.Y393C | Missense Mutation (SNP) | VAF 42/536 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- HACD4 | c.213A>C p.E71D | Missense Mutation (SNP) | VAF 25/373 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HS3ST4 | c.1214C>G p.A405G | Missense Mutation (SNP) | VAF 67/652 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- KCNK16 | c.82G>T p.G28C | Missense Mutation (SNP) | VAF 24/289 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LAP3 | c.647C>G p.A216G | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2
- LGALS8 | c.616G>A p.E206K (on ENST00000341872; = p.E248K on NM_006499.4) | Missense Mutation (SNP) | VAF 61/558 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- LRATD1 | c.194C>A p.P65Q | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2
- MAP3K2 | c.1138A>G p.R380G | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.015); called by muse, mutect2
- MROH2B | c.3355delinsAA p.Q1119Kfs*10 | Frame Shift Ins (INS) | VAF 42/375 reads (11%) | called by pindel, varscan2*
- MUC12 | c.14387A>G p.E4796G (on ENST00000379442; = p.E4653G on NM_001164462.1) | Missense Mutation (SNP) | VAF 20/538 reads (4%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- MUC5B | c.12966C>G p.S4322R | Missense Mutation (SNP) | VAF 24/403 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.308); called by muse, mutect2
- MYH9 | c.3223A>T p.K1075* | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- NOD2 | c.1359G>C p.E453D | Missense Mutation (SNP) | VAF 24/329 reads (7%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.738); called by muse, mutect2
- NPTX2 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 9/196 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2
- NPY1R | c.176T>A p.L59Q | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- NWD2 | c.4651C>A p.L1551I | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- OR14K1 | c.865T>A p.C289S | Missense Mutation (SNP) | VAF 45/432 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2B2 | c.443C>A p.S148Y | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- OR5T2 | c.490G>T p.A164S | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- OSBPL8 | c.2540A>G p.N847S | Missense Mutation (SNP) | VAF 20/249 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- PIGM | c.1024T>A p.L342I | Missense Mutation (SNP) | VAF 68/1042 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2
- PPP1R42 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); called by muse, mutect2
- PPP2R3A | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 36/404 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.765); called by muse, mutect2
- PRKCSH | c.1216G>T p.G406W | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PSMD11 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRH | c.2950T>C p.W984R | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PZP | c.399C>A p.D133E | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAD54L | c.2047C>A p.R683S | Missense Mutation (SNP) | VAF 48/656 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- RAX | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.994); called by muse, mutect2
- RPS7 | c.29A>T p.K10M | Missense Mutation (SNP) | VAF 37/636 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SALL1 | c.465C>A p.S155R | Missense Mutation (SNP) | VAF 38/608 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.023); called by muse, mutect2
- SGO2 | c.1432G>C p.G478R | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.272); called by muse, mutect2
- SGSM2 | c.899A>G p.N300S | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2
- SLC17A6 | c.27G>T p.L9F | Missense Mutation (SNP) | VAF 19/244 reads (8%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.025); called by muse, mutect2
- SLITRK3 | c.2147G>T p.G716V | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.2); called by muse, mutect2
- STRN4 | c.1972G>T p.D658Y | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- TCF12 | c.551G>A p.R184K | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- TNFSF18 | c.385T>C p.Y129H | Missense Mutation (SNP) | VAF 24/540 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRMT11 | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2
- TUBGCP5 | c.626A>T p.E209V | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2
- XIRP2 | c.2314A>T p.N772Y (on ENST00000628543; = p.N947Y on NM_152381.6) | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ZNF354A | c.338A>T p.N113I | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATRAID | c.414G>A p.E138= (on ENST00000611786; = p.E25= on NM_016085.5) | Silent (SNP) | VAF 20/328 reads (6%) | called by muse, mutect2
- CCDC74A | c.450G>C p.G150= | Silent (SNP) | VAF 14/496 reads (3%) | called by muse, mutect2
- CD226 | c.807C>T p.T269= | Silent (SNP) | VAF 22/270 reads (8%) | called by muse, mutect2
- CDH9 | c.54A>T p.T18= | Silent (SNP) | VAF 68/469 reads (14%) | called by muse, mutect2, varscan2
- DENND3 | c.2157C>T p.N719= | Silent (SNP) | VAF 56/486 reads (12%) | catalogued as rs761923637, COSV52800755, COSV52807635; called by muse, mutect2, varscan2
- FCAMR | c.567C>T p.S189= | Silent (SNP) | VAF 59/469 reads (13%) | called by muse, mutect2, varscan2
- KCNB1 | c.1950T>C p.S650= | Silent (SNP) | VAF 34/502 reads (7%) | catalogued as rs767412426; called by muse, mutect2
- LILRA4 | c.165C>A p.A55= | Silent (SNP) | VAF 12/182 reads (7%) | called by muse, mutect2
- LINGO2 | c.963C>G p.R321= | Silent (SNP) | VAF 16/227 reads (7%) | called by muse, mutect2
- LINS1 | c.900C>A p.I300= | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as COSV59078982; called by muse, mutect2
- LMOD1 | c.990C>T p.P330= | Silent (SNP) | VAF 28/496 reads (6%) | catalogued as rs758404662, COSV100939114; called by muse, mutect2
- MID2 | c.1818C>T p.G606= | Silent (SNP) | VAF 6/55 reads (11%) | called by muse, varscan2
- OR5D13 | c.108C>T p.V36= | Silent (SNP) | VAF 26/400 reads (7%) | catalogued as rs200492542; called by muse, mutect2
- PKD1L1 | c.2808C>T p.V936= | Silent (SNP) | VAF 14/214 reads (7%) | called by muse, mutect2
- PNKP | c.777G>C p.R259= | Silent (SNP) | VAF 16/410 reads (4%) | called by muse, mutect2
- PRKCG | c.1218G>C p.G406= | Silent (SNP) | VAF 24/312 reads (8%) | catalogued as COSV54728668; called by muse, mutect2
- RAB2B | c.54G>T p.G18= | Silent (SNP) | VAF 28/462 reads (6%) | called by muse, mutect2
- RHAG | c.228C>A p.G76= | Silent (SNP) | VAF 33/577 reads (6%) | called by muse, mutect2
- RNASEH2A | c.384A>C p.A128= | Silent (SNP) | VAF 34/660 reads (5%) | called by muse, mutect2
- SLCO4C1 | c.429G>A p.L143= | Silent (SNP) | VAF 20/410 reads (5%) | called by muse, mutect2
- SMARCB1 | c.894C>T p.G298= (on ENST00000263121; = p.G344= on NM_003073.5) | Silent (SNP) | VAF 66/870 reads (8%) | catalogued as rs149451748; ClinVar: likely benign / benign / conflicting interpretations of pathogenicity; called by muse, mutect2
- TMEM132C | c.1200C>A p.P400= | Silent (SNP) | VAF 9/192 reads (5%) | called by muse, mutect2
- ZFHX4 | c.3600A>G p.T1200= | Silent (SNP) | VAF 41/322 reads (13%) | called by muse, mutect2, varscan2
- AC007036.4 | chr7:30118023 G>T | 5'Flank (SNP) | VAF 9/149 reads (6%) | called by muse, mutect2
- ADAMTS6 | c.2575+73G>T | Intron (SNP) | VAF 24/444 reads (5%) | called by muse, mutect2
- BRD9 | c.1525+1141A>T | Intron (SNP) | VAF 39/336 reads (12%) | called by muse, mutect2, varscan2
- DCHS2 | n.7272T>A | RNA (SNP) | VAF 34/454 reads (7%) | called by muse, mutect2
- GOT2 | c.854-28G>C | Intron (SNP) | VAF 16/202 reads (8%) | catalogued as COSV55333832; called by muse, mutect2
- KLK2 | chr19:50873432 C>G | 5'Flank (SNP) | VAF 10/176 reads (6%) | catalogued as COSV100319929; called by muse, mutect2
- OXSR1 | c.951+9G>T | Intron (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- PNKP | c.198+47G>C | Intron (SNP) | VAF 24/308 reads (8%) | called by muse, mutect2
- ZNF446 | c.713-15C>T | Intron (SNP) | VAF 9/197 reads (5%) | called by muse, mutect2
